Somatic mutation profile of tumor specimen TCGA-66-2757-01A (aliquot TCGA-66-2757-01A-01D-1522-08) from TCGA case TCGA-66-2757, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-66-2757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eac56a8-556b-4b29-b2bc-5793c6ad0f40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2757-11A (Solid Tissue Normal), aliquot TCGA-66-2757-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2194b74e-3f7e-4b0c-b6f5-8c445a24b0ed

The open-access MAF lists 262 somatic variants for this specimen: 202 protein-altering or splice-affecting, 54 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 54, Splice Site 12, Nonsense Mutation 9, Frame Shift Del 6, Intron 4, RNA 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 46/60 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3199C>A p.L1067I | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV59391189; called by muse, mutect2, varscan2
- ABCD1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782159028, COSV54387281; called by muse, mutect2, varscan2
- ABCG1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 145/160 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV59209161; called by muse, mutect2, varscan2
- ADGRG4 | c.3207G>T p.Q1069H | Missense Mutation (SNP) | VAF 223/595 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV54964228; called by muse, mutect2, varscan2
- ADRB2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.479); catalogued as COSV60006085; called by muse, mutect2, varscan2
- AIFM3 | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV59002812; called by muse, mutect2, varscan2
- ALLC | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52993506, COSV52997535; called by muse, mutect2, varscan2
- ANGPTL5 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57534291; called by muse, mutect2, varscan2
- AQP12A | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422147404, COSV61837607; called by muse, mutect2, varscan2
- AQP12A | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61837611; called by muse, mutect2, varscan2
- ARHGEF35 | c.1156A>G p.R386G | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100967765; called by muse, mutect2, varscan2
- ARHGEF4 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV58127976; called by muse, mutect2, varscan2
- ATG7 | c.2028A>T p.L676F | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61615013; called by muse, mutect2, varscan2
- ATP8B4 | c.3104T>C p.I1035T | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV52722195; called by muse, mutect2, varscan2
- BAAT | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs1366423369, COSV52290511; called by muse, mutect2, varscan2
- BAHCC1 | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1555654887, COSV57032016; called by muse, mutect2
- BTBD3 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV54780946; called by muse, mutect2, varscan2
- C19orf44 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55614151; called by muse, mutect2, varscan2
- CAMK1G | c.1376C>G p.A459G | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV50524888; called by muse, mutect2
- CCDC185 | c.1708C>A p.Q570K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV64821641; called by muse, mutect2, varscan2
- CCDC22 | c.1212+1G>T p.X404_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV66051891; called by muse, mutect2, varscan2
- CDH10 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52591050, COSV52593301, COSV52593638; called by muse, mutect2, varscan2
- CDH18 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CDH18 | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs368155280, COSV56951957; called by muse, mutect2, varscan2
- CEP162 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV57623118; called by muse, mutect2, varscan2
- CHRNA1 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV53682806, COSV53684609; called by muse, varscan2
- CLCN6 | c.2397G>A p.M799I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.549); catalogued as COSV56742491; called by muse, varscan2
- CLSTN2 | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 49/182 reads (27%) | catalogued as rs1292488639, COSV71724013; called by muse, mutect2, varscan2
- COLEC12 | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV68372996; called by muse, mutect2, varscan2
- CPS1 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51821267, COSV99242488; called by muse, mutect2, varscan2
- CPT1C | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54921577; called by muse, mutect2, varscan2
- CSF1R | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV53840885; called by muse, mutect2, varscan2
- CSMD2 | c.6181G>A p.D2061N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749635413, COSV53905822, COSV53951061; called by muse, mutect2, varscan2
- CXorf56 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as COSV57439023; called by muse, mutect2, varscan2
- DCAKD | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs755858662, COSV60203146; called by muse, mutect2, varscan2
- DDX11 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV52509237; called by muse, mutect2, varscan2
- DHX36 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100274077, COSV57676224; called by muse, mutect2, varscan2
- DLC1 | c.3862G>A p.E1288K (on ENST00000276297 / NM_001348081.2; = p.E851K on NM_006094.5) | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs377705483; called by muse, mutect2, varscan2
- DNTT | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 73/104 reads (70%) | catalogued as COSV64522857; called by muse, mutect2, varscan2
- DSEL | c.1274G>A p.W425* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | catalogued as rs1285690393, COSV59493860; called by muse, mutect2
- EP400 | c.9055A>T p.T3019S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57783218; called by muse, mutect2, varscan2
- EPHA6 | c.3333C>G p.S1111R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV67589653; called by muse, mutect2, varscan2
- EPRS1 | c.3694A>C p.S1232R | Missense Mutation (SNP) | VAF 27/434 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV65101018; called by muse, mutect2
- ERICH3 | c.4289G>T p.G1430V | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV58615187; called by muse, mutect2, varscan2
- FAM47A | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV100649716, COSV60499181; called by muse, varscan2
- FAT3 | c.4544C>T p.T1515I | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV53159483; called by muse, mutect2, varscan2
- FBN2 | c.3294C>G p.C1098W | Missense Mutation (SNP) | VAF 85/124 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52537825; called by muse, mutect2, varscan2
- FBXL20 | c.1053C>A p.C351* | Nonsense Mutation (SNP) | VAF 61/144 reads (42%) | catalogued as COSV52897795, COSV52902984; called by muse, mutect2, varscan2
- FGF10 | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 63/216 reads (29%) | catalogued as COSV99240757; called by muse, mutect2, varscan2
- FGF18 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 54/75 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51128736; called by muse, mutect2, varscan2
- FOXJ2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV50822712; called by muse, mutect2, varscan2
- FZD3 | c.1853C>A p.T618K | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); catalogued as COSV53537262; called by muse, mutect2, varscan2
- GABRA2 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as COSV100734232, COSV62918399; called by muse, mutect2, varscan2
- GABRA3 | c.455T>A p.F152Y | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV64803769; called by muse, mutect2, varscan2
- GABRQ | c.748+2T>A p.X250_splice | Splice Site (SNP) | VAF 80/217 reads (37%) | catalogued as COSV64781490, COSV64783590; called by muse, mutect2, varscan2
- GALNTL5 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV67180936; called by muse, mutect2, varscan2
- GBA3 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV72438564; called by muse, mutect2
- GJA8 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | catalogued as COSV53790201; called by muse, mutect2, varscan2
- GPNMB | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51698036, COSV51700439; called by muse, mutect2, varscan2
- GPR17 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55756702; called by muse, mutect2, varscan2
- GPR83 | c.967A>G p.N323D | Missense Mutation (SNP) | VAF 171/267 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV54720266; called by muse, mutect2, varscan2
- GRIK2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV59729281, COSV59761825; called by muse, mutect2, varscan2
- GSTM2 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99598279, COSV99598288; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 84/192 reads (44%) | catalogued as COSV57133492; called by muse, mutect2, varscan2
- HPS5 | c.1117G>T p.A373S (on ENST00000349215 / NM_181507.2; = p.A259S on NM_007216.4) | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100752337, COSV61687897; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99404403; called by muse, mutect2, varscan2
- HTR2C | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194076654, COSV52220873; called by muse, mutect2, varscan2
- ICAM4 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV53426656; called by muse, mutect2, varscan2
- IFT122 | c.3538G>C p.D1180H (on ENST00000348417 / NM_052989.3; = p.D1121H on NM_018262.4) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as COSV56206928; called by muse, mutect2, varscan2
- IL17RA | c.1143G>C p.W381C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60055608; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1858C>A p.R620S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV100147047, COSV100148571, COSV56290459; called by muse, mutect2, varscan2
- INPP5E | c.1200G>C p.Q400H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65497024; called by muse, mutect2, varscan2
- IPO4 | c.1156C>G p.H386D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV55781414; called by muse, mutect2, varscan2
- ITGB1BP2 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1030739067, COSV52139812; called by muse, mutect2, varscan2
- JPH2 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60697781; called by muse, mutect2, varscan2
- KCNT1 | c.2423C>G p.S808C (on ENST00000488444; = p.S827C on NM_020822.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53701968, COSV53708587; called by muse, mutect2, varscan2
- KCTD8 | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 176/465 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as COSV63594466; called by muse, mutect2, varscan2
- KDM5A | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66994385; called by muse, mutect2, varscan2
- KDR | c.2630G>T p.S877I | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55773415, COSV55777066; called by muse, mutect2, varscan2
- KIAA0408 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 126/256 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100846981, COSV64109355; called by muse, mutect2, varscan2
- KIF1B | c.4371G>A p.M1457I (on ENST00000377086 / NM_001365952.1; = p.M1411I on NM_015074.3) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV55814103; called by muse, mutect2, varscan2
- LAMA3 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV58076645; called by muse, mutect2, varscan2
- LRRTM4 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV69138812, COSV69141526; called by muse, mutect2, varscan2
- LZTR1 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53150699; called by muse, mutect2, varscan2
- MAGEA10 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV54885482; called by muse, mutect2, varscan2
- MAGEB2 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781541; called by muse, mutect2, varscan2
- MCF2 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV58492587; called by muse, varscan2
- MET | c.2731-1G>C p.X911_splice | Splice Site (SNP) | VAF 91/260 reads (35%) | catalogued as COSV59257663; called by muse, mutect2, varscan2
- MGAM | c.4493A>T p.Q1498L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV72075380; called by muse, mutect2, varscan2
- MIGA1 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs1171889549, COSV66224619; called by muse, mutect2
- MOGAT3 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56176533; called by muse, mutect2, varscan2
- MPP3 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV68199050; called by muse, mutect2, varscan2
- MSH6 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV52285560; called by muse, mutect2, varscan2
- MUC16 | c.21606C>G p.D7202E | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.047); catalogued as COSV67485621; called by muse, mutect2, varscan2
- MUC17 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 182/410 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60299841; called by mutect2, varscan2
- MYH15 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56304892, COSV56317342; called by muse, mutect2, varscan2
- MYL1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.101); catalogued as COSV58974035; called by muse, mutect2, varscan2
- MYL12B | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV52899087; called by muse, mutect2, varscan2
- NAMPT | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55996281; called by muse, mutect2, varscan2
- NCBP2L | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100966505; called by muse, mutect2, varscan2
- NCS1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV64963412; called by muse, mutect2, varscan2
- NELL1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV54311160; called by muse, mutect2, varscan2
- NES | c.4407G>C p.W1469C | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV63962455; called by muse, mutect2, varscan2
- NKAP | c.530C>G p.T177S | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65056826; called by muse, mutect2, varscan2
- NLRP13 | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61623676; called by muse, mutect2, varscan2
- NOS1AP | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62638962; called by muse, mutect2, varscan2
- NPAS3 | c.172G>A p.D58N (on ENST00000356141 / NM_001164749.2; = p.D28N on NM_022123.3) | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.159); catalogued as COSV58100625, COSV58104910; called by muse, mutect2, varscan2
- NR4A1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV54486715; called by muse, mutect2, varscan2
- NRAP | c.167+1G>T p.X56_splice | Splice Site (SNP) | VAF 28/42 reads (67%) | catalogued as COSV63492642, COSV63493236; called by muse, mutect2, varscan2
- OLFM2 | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV53432949; called by muse, mutect2, varscan2
- OLFML2A | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.86); PolyPhen probably damaging (1); catalogued as rs751418527, COSV56585091; called by muse, mutect2, varscan2
- OR2A5 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68739031; called by muse, mutect2, varscan2
- OR4K5 | c.884A>T p.K295M | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV60004834; called by muse, mutect2, varscan2
- OR4X2 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56584789; called by muse, mutect2
- OR51B2 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60917466; called by muse, mutect2, varscan2
- OR6K3 | c.198G>C p.R66S (on ENST00000368146; = p.R50S on NM_001005327.2) | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV63746286; called by muse, mutect2, varscan2
- OR7D2 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV60139969, COSV60140944; called by muse, mutect2, varscan2
- OR8G5 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100422529; called by muse, mutect2, varscan2
- OR8H3 | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV57910896; called by muse, mutect2
- OSBPL11 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.086); catalogued as COSV56175877; called by muse, mutect2, varscan2
- PCARE | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 125/302 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV59057023; called by muse, mutect2, varscan2
- PCDHA1 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65376288; called by muse, mutect2, varscan2
- PCDHB8 | c.996C>A p.C332* | Nonsense Mutation (SNP) | VAF 9/179 reads (5%) | catalogued as COSV50804795; called by muse, mutect2
- PCDHGB2 | c.1924C>A p.L642M | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54010054; called by muse, mutect2, varscan2
- PCDHGB5 | c.1904G>C p.R635P | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54010066; called by muse, mutect2, varscan2
- PDZRN4 | c.2300C>A p.T767N (on ENST00000402685 / NM_001164595.2; = p.T509N on NM_013377.4) | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV54213176; called by muse, mutect2, varscan2
- PHYHIP | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV58689212; called by muse, mutect2, varscan2
- PLCB1 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62063857; called by muse, mutect2, varscan2
- PLXNA3 | c.4630C>A p.Q1544K | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV63755168; called by muse, mutect2, varscan2
- PLXNB1 | c.6007G>C p.D2003H | Missense Mutation (SNP) | VAF 85/119 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489282, COSV56493240; called by muse, mutect2, varscan2
- POLA1 | c.1070-1G>T p.X357_splice | Splice Site (SNP) | VAF 85/211 reads (40%) | catalogued as COSV66889820; called by muse, mutect2, varscan2
- PPM1G | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59771220; called by muse, varscan2
- PRKN | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 113/220 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV58198078, COSV58251060; called by muse, mutect2, varscan2
- PRUNE2 | c.8182C>A p.P2728T | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV65046214, COSV65047843; called by muse, mutect2, varscan2
- PSMB8 | c.148-1G>T p.X50_splice (on ENST00000374882 / NM_148919.4; = p.X46_splice on NM_004159.5) | Splice Site (SNP) | VAF 27/93 reads (29%) | catalogued as COSV62754449, COSV62755500; called by muse, mutect2, varscan2
- PTPN21 | c.2528G>T p.R843L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs757930452, COSV60851149; called by muse, mutect2
- RBM47 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55934868; called by muse, mutect2, varscan2
- RETNLB | c.209-1G>T p.X70_splice | Splice Site (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99848837; called by muse, mutect2, varscan2
- RFX7 | c.2492A>T p.H831L (on ENST00000559447 / NM_001368074.1; = p.H928L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV57967463, COSV57969658; called by muse, mutect2, varscan2
- RIMS4 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65720536; called by muse, mutect2, varscan2
- RLIM | c.591A>T p.E197D | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV60328524; called by muse, mutect2, varscan2
- RNASEL | c.2203G>T p.G735W | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV62377715; called by muse, mutect2, varscan2
- RNF34 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63443239; called by muse, mutect2, varscan2
- RYR1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs923613797, COSV62107262; called by muse, mutect2, varscan2
- SASH3 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV63556529; called by muse, mutect2, varscan2
- SCML2 | c.2063G>T p.C688F | Missense Mutation (SNP) | VAF 113/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52624213; called by muse, mutect2, varscan2
- SCN3A | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51820603; called by muse, varscan2
- SCN4A | c.5058G>T p.E1686D | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV71128567; called by muse, mutect2, varscan2
- SEC16A | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV51537628; called by muse, mutect2, varscan2
- SELP | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 179/421 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55256598; called by muse, mutect2, varscan2
- SEMA6D | c.3175G>C p.V1059L (on ENST00000316364 / NM_153618.2; = p.V997L on NM_020858.2) | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV60382301; called by muse, mutect2, varscan2
- SEZ6L2 | c.2216T>C p.L739P (on ENST00000308713 / NM_001114099.3; = p.L669P on NM_012410.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58102654; called by muse, mutect2, varscan2
- SIGLEC7 | c.630C>A p.H210Q | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV58315338, COSV58317390; called by muse, mutect2, varscan2
- SLAMF6 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 149/375 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV63587941; called by muse, mutect2, varscan2
- SLC22A14 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs749090976, COSV56198436, COSV56198970; called by muse, mutect2, varscan2
- SLC25A34 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53818222; called by muse, mutect2, varscan2
- SLC5A8 | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73311077; called by muse, mutect2, varscan2
- SLCO1B3 | c.628+2T>A p.X210_splice | Splice Site (SNP) | VAF 41/138 reads (30%) | catalogued as COSV53938227, COSV53944270; called by muse, mutect2, varscan2
- SMG7 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV61633683; called by muse, mutect2
- SPART | c.1736A>C p.Y579S | Missense Mutation (SNP) | VAF 69/83 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62087673; called by muse, mutect2, varscan2
- SPHKAP | c.3645C>G p.S1215R | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60869041, COSV60890912; called by muse, mutect2, varscan2
- SPTBN4 | c.5527G>T p.A1843S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as COSV100152223, COSV58956892; called by muse, mutect2, varscan2
- SSX1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 159/387 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV65356152; called by muse, mutect2, varscan2
- STAB2 | c.4455G>T p.K1485N | Missense Mutation (SNP) | VAF 150/351 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV66344911; called by muse, mutect2, varscan2
- STARD13 | c.2708G>T p.G903V (on ENST00000336934 / NM_001243476.3; = p.G785V on NM_052851.3) | Missense Mutation (SNP) | VAF 106/145 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV55229500, COSV99715918; called by muse, mutect2, varscan2
- SYNE1 | c.26134G>A p.V8712I (on ENST00000367255 / NM_182961.4; = p.V8664I on NM_033071.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.718); catalogued as COSV55070882; called by muse, mutect2, varscan2
- SYT10 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57344223; called by muse, mutect2
- THOC2 | c.4270G>T p.V1424L | Missense Mutation (SNP) | VAF 181/456 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762461070, COSV55553525; called by muse, mutect2, varscan2
- THOC2 | c.3370T>A p.L1124M | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55553544; called by muse, mutect2, varscan2
- TMTC4 | c.1162C>A p.L388M (on ENST00000376234 / NM_001350577.2; = p.L407M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV60893357, COSV60893648; called by muse, mutect2, varscan2
- TNR | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV54907178; called by muse, mutect2
- TRIM43 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV55529950, COSV99720013; called by muse, mutect2, varscan2
- TRIM49 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs756095582, COSV61671521; called by muse, mutect2
- TRIP12 | c.4918C>G p.Q1640E | Missense Mutation (SNP) | VAF 17/369 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV52270766; called by muse, mutect2
- TRPC4AP | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV52683371; called by muse, mutect2, varscan2
- TSHR | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 105/156 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs777698828, COSV53325750, COSV53328811; called by muse, mutect2, varscan2
- TTN | c.12982C>A p.P4328T (on ENST00000591111; = p.P4282T on NM_003319.4) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as COSV60166934; called by muse, mutect2, varscan2
- UBAC1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV65614522; called by muse, mutect2, varscan2
- UBE3A | c.2491G>T p.G831C | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51669629; called by muse, mutect2, varscan2
- UCHL5 | c.141-1G>T p.X47_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as COSV66486950; called by muse, mutect2, varscan2
- UNC5D | c.1854G>T p.L618F | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV54825551; called by muse, mutect2, varscan2
- USP51 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV72351883; called by muse, mutect2
- WASHC2A | c.3977A>T p.K1326M | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV50955447; called by muse, mutect2, varscan2
- XPO7 | c.2629C>T p.H877Y | Missense Mutation (SNP) | VAF 174/250 reads (70%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV53018950; called by muse, mutect2, varscan2
- ZFP37 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV65288155, COSV65288183; called by muse, mutect2, varscan2
- ZMIZ1 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as COSV57901989; called by muse, mutect2
- ZNF449 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59347804; called by muse, mutect2, varscan2
- ZNF454 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 50/81 reads (62%) | catalogued as COSV60769846; called by muse, mutect2, varscan2
- ZNF479 | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV58642570; called by muse, mutect2
- ZNF521 | c.1499A>T p.H500L | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64130716; called by muse, mutect2, varscan2
- IGHV3-73 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- IGKV3-7 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LRRTM1 | c.178del p.A60Rfs*29 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- LYZL6 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NEB | c.4151del p.P1384Lfs*36 | Frame Shift Del (DEL) | VAF 68/207 reads (33%) | called by mutect2, pindel, varscan2
- NR1H4 | c.143del p.G48Dfs*66 (on ENST00000551379 / NM_001206993.2; = p.G38Dfs*66 on NM_005123.4) | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- PGAM4 | c.745del p.Q249Rfs*45 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | called by mutect2, pindel
- PNMA5 | c.567del p.W189Cfs*34 | Frame Shift Del (DEL) | VAF 59/166 reads (36%) | called by mutect2, pindel, varscan2
- SERPINF1 | c.283+2_283+3insCT p.X95_splice | Splice Site (INS) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- TPTE | c.1324G>T p.V442F (on ENST00000618007 / NM_199261.4; = p.V424F on NM_199259.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZNF211 | c.1365_1366del p.C455Wfs*8 (on ENST00000347302 / NM_198855.4; = p.C468Wfs*8 on NM_006385.5) | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | called by pindel, varscan2
- AOC3 | c.1905C>A p.T635= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV53828317; called by muse, mutect2, varscan2
- BTBD3 | c.678T>C p.C226= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV54780933; called by muse, mutect2, varscan2
- BTNL9 | c.675G>A p.V225= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV59798598; called by muse, mutect2, varscan2
- CCSER1 | c.42G>T p.R14= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs562834496, COSV61457981; called by muse, mutect2, varscan2
- COL22A1 | c.918G>A p.R306= | Silent (SNP) | VAF 104/127 reads (82%) | catalogued as COSV57354553; called by muse, mutect2, varscan2
- DEXI | c.121C>T p.L41= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs758435374, COSV59328931; called by muse, mutect2, varscan2
- DIPK2A | c.588C>T p.N196= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV59858205; called by muse, mutect2, varscan2
- DSG4 | c.2133C>T p.S711= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as rs766900981, COSV57396295; called by muse, mutect2, varscan2
- FAR2 | c.75G>T p.V25= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV51728792; called by muse, mutect2, varscan2
- FBXO38 | c.3507G>T p.V1169= (on ENST00000340253 / NM_205836.3; = p.V1094= on NM_030793.5) | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as COSV57030710; called by muse, mutect2
- FLNA | c.5347C>T p.L1783= (on ENST00000369850 / NM_001110556.2; = p.L1775= on NM_001456.3) | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV61049197; called by muse, mutect2, varscan2
- GNL3L | c.1359G>A p.T453= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV60577392; called by muse, mutect2, varscan2
- GRID2 | c.2580C>A p.G860= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as COSV56249793; called by muse, mutect2, varscan2
- HOXA3 | c.1092C>T p.P364= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs140908739, COSV57828339; called by muse, mutect2, varscan2
- HOXD3 | c.1281C>G p.P427= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV50884399; called by muse, mutect2, varscan2
- HRH2 | c.387G>T p.L129= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as COSV51574740, COSV51575702; called by muse, mutect2, varscan2
- HS3ST3A1 | c.669G>T p.R223= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as COSV52378446; called by muse, mutect2, varscan2
- KHNYN | c.424C>T p.L142= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as COSV52162853; called by muse, mutect2, varscan2
- KRBA1 | c.348G>T p.L116= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55443596; called by muse, mutect2
- KRT17 | c.654G>T p.L218= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as COSV60861733, COSV60861978; called by muse, mutect2
- KRT85 | c.276C>A p.P92= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV57737945; called by muse, mutect2, varscan2
- LATS1 | c.1518A>G p.P506= | Silent (SNP) | VAF 94/310 reads (30%) | catalogued as rs767012290, COSV53597859; called by muse, varscan2
- LHCGR | c.1482T>C p.S494= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV54301639; called by muse, mutect2, varscan2
- LMOD2 | c.207G>T p.L69= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV71755797; called by muse, mutect2, varscan2
- LPCAT1 | c.1506A>G p.A502= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as COSV52040449; called by muse, mutect2, varscan2
- LRFN2 | c.369G>T p.L123= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57832888; called by muse, mutect2, varscan2
- MAG | c.1764T>G p.G588= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV62702393; called by muse, mutect2, varscan2
- MAGEB3 | c.954C>A p.V318= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs749159690, COSV64397609; called by muse, mutect2, varscan2
- MAN2B1 | c.1251G>T p.A417= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs1055070863, COSV55474615; called by muse, mutect2, varscan2
- MCF2 | c.1998G>C p.L666= | Silent (SNP) | VAF 62/189 reads (33%) | catalogued as COSV58492557; called by muse, varscan2
- MDGA1 | c.2124G>A p.L708= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51800448; called by muse, mutect2, varscan2
- MTOR | c.2172C>T p.A724= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV63876582; called by muse, mutect2, varscan2
- NOVA1 | c.315G>T p.T105= | Silent (SNP) | VAF 135/218 reads (62%) | catalogued as COSV57478942, COSV57485327; called by muse, mutect2, varscan2
- OR4D6 | c.210C>T p.D70= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as rs758945903, COSV55660723; called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 43/219 reads (20%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2, varscan2
- OR52B2 | c.450C>T p.V150= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV73209555; called by muse, mutect2, varscan2
- PCDHGA3 | c.1887G>A p.A629= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1173189539, COSV53966716; called by muse, mutect2, varscan2
- PEAK1 | c.3666G>A p.L1222= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs374175949; called by muse, mutect2, varscan2
- PICALM | c.1167G>A p.L389= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as COSV62673219; called by muse, mutect2, varscan2
- PLXNA3 | c.4629C>A p.L1543= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as COSV63755164; called by muse, mutect2, varscan2
- RTN4 | c.1650G>C p.L550= | Silent (SNP) | VAF 79/206 reads (38%) | catalogued as COSV58272448; called by muse, mutect2, varscan2
- RTP2 | c.303G>T p.T101= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs746348051, COSV64079352; called by muse, mutect2, varscan2
- S1PR2 | c.615C>T p.I205= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs200948899, COSV58485779; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL3 | c.1674C>A p.P558= | Silent (SNP) | VAF 4/6 reads (67%) | catalogued as COSV73306383; called by mutect2, varscan2
- SDCCAG8 | c.1272G>A p.K424= | Silent (SNP) | VAF 68/172 reads (40%) | catalogued as COSV59415460; called by muse, mutect2, varscan2
- SLC1A7 | c.1275C>G p.A425= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV57014340, COSV57016379; called by muse, mutect2, varscan2
- SUGCT | c.120A>G p.P40= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV59347891; called by muse, mutect2
- SYNE1 | c.5688T>C p.S1896= (on ENST00000367255 / NM_182961.4; = p.S1903= on NM_033071.3) | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as COSV55070934; called by muse, mutect2, varscan2
- THSD7B | c.2619C>G p.T873= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV55725807; called by muse, mutect2, varscan2
- TMEM266 | c.126G>A p.L42= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as COSV66381144; called by muse, mutect2, varscan2
- TPBG | c.702C>T p.P234= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as rs775912512, COSV63882500; called by muse, mutect2, varscan2
- USP25 | c.1281G>A p.T427= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs373634568; called by muse, mutect2, varscan2
- WNK3 | c.3660C>T p.S1220= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV63615487; called by muse, mutect2, varscan2
- ZNF135 | c.153C>A p.V51= | Silent (SNP) | VAF 102/236 reads (43%) | catalogued as COSV57884969; called by muse, mutect2, varscan2
- ATP11C | c.*35C>A | 3'UTR (SNP) | VAF 52/158 reads (33%) | catalogued as COSV100558234; called by muse, mutect2, varscan2
- FN1 | c.3797-1348G>A | Intron (SNP) | VAF 32/123 reads (26%) | catalogued as rs764149816, COSV60561123; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27640C>T | Intron (SNP) | VAF 20/46 reads (43%) | catalogued as COSV64795327; called by muse, mutect2, varscan2
- KIF1B | c.2115+7319G>A | Intron (SNP) | VAF 38/79 reads (48%) | catalogued as rs776976329, COSV99823708; called by muse, mutect2, varscan2
- OFCC1 | n.280G>T | RNA (SNP) | VAF 102/319 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.10303+2627A>T | Intron (SNP) | VAF 58/165 reads (35%) | catalogued as COSV60272740; called by muse, mutect2, varscan2
